TCGA case TCGA-HN-A2OB — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Ontario Institute for Cancer Research (OICR). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/61204cdf-3b1c-44a1-bda6-0fef1ac4a333

Demographics
Sex at birth: female; Country of residence at enrollment: Canada; Age at index: 45 years; Vital status: Dead; Days to death: 1,900 days (5.2 years).

Diagnoses (4)
1. Lobular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8520/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 45.6 years (16,672 days); Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, NOS / Breast, Right Lower Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 10; Micrometastasis present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Epirubicin + Fluorouracil; Days to treatment start: 105 days; Days to treatment end: 147 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 168 days; Days to treatment end: 210 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 242 days; Days to treatment end: 276 days; Treatment dose: 50 Gy; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
2. Metastasis of diagnosis 1 (Lobular carcinoma, NOS), site: Bone, NOS. Age at diagnosis: 49.9 years (18,215 days); Days to diagnosis: 1,543 days (4.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Lobular carcinoma, NOS), site: Bone, NOS. Age at diagnosis: 49.9 years (18,224 days); Days to diagnosis: 1,552 days (4.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
4. Metastasis of diagnosis 1 (Lobular carcinoma, NOS), site: Specified parts of peritoneum. Age at diagnosis: 50.2 years (18,345 days); Days to diagnosis: 1,673 days (4.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (6 entries)
- Day 1,543 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 1,543 days (4.2 years).
- Day 1,552 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 1,552 days (4.2 years).
- Day 1,673 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Specified parts of peritoneum; Days to progression: 1,673 days (4.6 years).
- Days to follow up: 1,849 days (5.1 years); Disease response: With Tumor.
- Days to follow up: 1,883 days (5.2 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 1,900.

Molecular and laboratory tests
- ERBB2 (FISH): 1.2; Cell count: 60; Specialized molecular test: Signal ratio.
- ERBB2 (FISH): Copy Number Reported; Copy number: 2; Cell count: 60.
- ERBB2 (IHC): Negative.
- ERBB2 (IHC): Negative; Staining intensity value: 1+.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Positive.
- ESR1 (IHC): Positive; Staining intensity scale: 3 Point Scale; Staining intensity value: 3+.
- ESR1 (IHC): Positive; Staining intensity scale: 4 Point Scale; Staining intensity value: 3+.
- PGR (IHC): Positive.
- PGR (IHC): Positive; Staining intensity scale: 3 Point Scale; Staining intensity value: 2+.
- PGR (IHC): Positive; Staining intensity scale: 4 Point Scale; Staining intensity value: 2+.
- Test (FISH): Copy Number Reported; Copy number: 1.7; Cell count: 60.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HN-A2OB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 320 mg.
  Slide TCGA-HN-A2OB-01A-02-TSB: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 65; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-HN-A2OB-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HN-A2OB-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: With tumor; Lymph nodes examined: Yes; Her2 cent17 ratio: 1.2; Axillary staging method: Sentinel node biopsy alone; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: Infiltrating Lobular Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: No; Method initial path diagnosis: Core needle biopsy; Prospective collection: No; Retrospective collection: Yes; Her2 copy number: 2.0.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right; Anatomic organ subdivision: Right Lower Outer Quadrant.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,900 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,900 days; disease-free interval: event (new tumor event after initially disease-free), 1,543 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,543 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HN-A2OB-01A-21D-A27O-01): tumor purity 0.42, ploidy 2.02, whole-genome doublings 0.
